Gene-level copy-number profile of tumor specimen TCGA-MT-A7BN-01A from TCGA case TCGA-MT-A7BN, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 74.4 years (27,162 days).
Specimen TCGA-MT-A7BN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.df0c95a4-9422-4161-833e-4b85fed597f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MT-A7BN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2b6fd793-7f99-4454-942c-e133d322b23a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,775; copy number 2: 18,823; copy number 3: 24,425; copy number 4: 8,314; copy number 5: 4,511; copy number 6: 696; copy number 7: 248; copy number 8: 200; copy number 9: 140; copy number 10: 266; copy number 11: 110; copy number 12: 166; copy number 13: 19; copy number 15: 25; copy number 17: 15; copy number 18: 12; copy number 19: 23; copy number 20: 8; copy number 21: 1; copy number 25: 11; copy number 31: 2; copy number 32: 4; copy number 34: 9; copy number 37: 5; copy number 44: 2; copy number 47: 1; copy number 59: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MT-A7BN-01A-12D-A34I-01): tumor purity 0.51, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,273 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:13,316,235–14,948,424, 35 genes, copy number 7–12: NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.2, AC090952.1, CCDC174, C3orf20, AC090957.1, AC087591.1, LINC02011, FGD5, FGD5-AS1.
- chr3:96,753,185–97,752,460, 4 genes, copy number 7 (within-gene range 3–11): RCC2P5, CDV3P1, AC109782.1, EPHA6.
- chr4:53,899,871–54,102,498, 10 genes, copy number 9: AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2.
- chr6:39,048,781–39,229,475, 4 genes, copy number 7 (within-gene range 3–7): GLP1R, SAYSD1, ANKRD18EP, KCNK5.
- chr6:40,713,411–43,369,647, 98 genes, copy number 7–9 (broad region; genes not listed).
- chr6:103,002,514–103,003,897, 1 gene, copy number 12: Z98755.1.
- chr6:104,487,095–107,824,317, 52 genes, copy number 7–59: AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4.
- chr6:115,358,498–116,060,891, 5 genes, copy number 32–47: AL606845.1, LINC02534, FRK, AL357141.1, TPI1P3.
- chr6:120,015,179–120,015,257, 1 gene, copy number 8: MIR3144.
- chr6:123,216,339–128,761,808, 56 genes, copy number 7–20: TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA.
- chr6:128,928,995–128,929,988, 1 gene, copy number 19: MESTP1.
- chr7:70,972–194,180, 8 genes, copy number 10: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3.
- chr7:52,165,235–57,837,046, 175 genes, copy number 10–44 (broad region; genes not listed).
- chr8:40,900,016–41,309,473, 7 genes, copy number 8: AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr8:101,337,496–101,492,499, 7 genes, copy number 7 (within-gene range 6–7): AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr10:32,446,140–32,882,874, 1 gene, copy number 8 (within-gene range 5–8): CCDC7.
- chr10:32,887,273–34,815,325, 23 genes, copy number 7–8 (within-gene range 5–8): ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16.
- chr10:35,896,874–36,442,392, 6 genes, copy number 8: LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2.
- chr10:42,408,168–52,298,423, 243 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr10:53,802,771–63,155,031, 74 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr10:70,478,767–81,875,133, 258 genes, copy number 10–19 (broad region; genes not listed).
- chr12:38,274,448–38,909,592, 6 genes, copy number 11: Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1.
- chr19:29,268,976–30,957,192, 29 genes, copy number 7–37: AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr19:31,655,356–35,813,299, 169 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
